Somatic mutation profile of tumor specimen TCGA-73-4670-01A (aliquot TCGA-73-4670-01A-01D-1265-08) from TCGA case TCGA-73-4670, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 69.9 years (25,526 days).
Specimen TCGA-73-4670-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f5b7851-72ea-438a-a5e6-e5c383eaf0e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-4670-11A (Solid Tissue Normal), aliquot TCGA-73-4670-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a86d8d33-7f58-483b-9e7a-d650c26322c4

The open-access MAF lists 389 somatic variants for this specimen: 299 protein-altering or splice-affecting, 78 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 250, Silent 78, Nonsense Mutation 20, Frame Shift Del 11, Intron 7, Splice Site 7, Frame Shift Ins 6, RNA 4, Splice Region 2, In Frame Ins 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 104/126 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.751G>C p.G251R | Missense Mutation (SNP) | VAF 16/23 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM981868, COSV58822591, COSV58830751; called by muse, mutect2, varscan2
- SUCLG1 | c.507del p.N171Tfs*35 | Frame Shift Del (DEL) | VAF 45/142 reads (32%) | catalogued as rs797046017; ClinVar: pathogenic; called by mutect2, pindel*, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 32/57 reads (56%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- A2M | c.2276C>A p.P759H | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588543; called by muse, mutect2, varscan2
- A2M | c.1851G>A p.S617= | Splice Region (SNP) | VAF 12/14 reads (86%) | catalogued as rs774999211, COSV59385266; called by muse, mutect2, varscan2
- AAK1 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV68643139; called by muse, mutect2, varscan2
- AASDH | c.2382G>T p.M794I | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV52705776; called by muse, mutect2
- ABCA12 | c.7114A>G p.K2372E (on ENST00000272895 / NM_173076.3; = p.K2054E on NM_015657.3) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.102); catalogued as COSV55955267; called by muse, mutect2, varscan2
- ABCB5 | c.2582G>T p.G861V (on ENST00000404938 / NM_001163941.2; = p.G416V on NM_178559.6) | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51704052, COSV51704692; called by muse, mutect2, varscan2
- ABCB8 | c.815A>T p.Q272L (on ENST00000297504 / NM_001282291.2; = p.Q255L on NM_007188.5) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV52503721; called by muse, mutect2, varscan2
- ABCC4 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as rs767254775, COSV65311557; called by muse, mutect2, varscan2
- ABCC5 | c.502C>G p.R168G | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55588908; called by muse, mutect2, varscan2
- ADAMTS16 | c.1800G>T p.R600S | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56985270; called by muse, mutect2, varscan2
- ADGRG4 | c.1080G>T p.M360I | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54953683; called by muse, mutect2, varscan2
- ADH4 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV55500687; called by muse, mutect2, varscan2
- AKAP9 | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV62343413; called by muse, mutect2, varscan2
- ANKRD7 | c.401G>T p.C134F | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV54554421, COSV99500870; called by muse, mutect2, varscan2
- ANP32E | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV58481832; called by muse, mutect2, varscan2
- APOB | c.6868G>T p.E2290* | Nonsense Mutation (SNP) | VAF 82/187 reads (44%) | catalogued as COSV51931568; called by muse, mutect2, varscan2
- AQP12A | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV100538679, COSV100539007; called by muse, mutect2, varscan2
- AQP12A | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100538683; called by muse, mutect2, varscan2
- ARHGAP6 | c.1690C>A p.H564N | Missense Mutation (SNP) | VAF 96/165 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57294473; called by muse, mutect2, varscan2
- ARHGEF11 | c.3301G>T p.E1101* | Nonsense Mutation (SNP) | VAF 62/151 reads (41%) | catalogued as COSV59353635; called by muse, mutect2, varscan2
- ARHGEF6 | c.413C>A p.A138E | Missense Mutation (SNP) | VAF 237/645 reads (37%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.056); catalogued as COSV51689461; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as COSV63437534, COSV63438757; called by muse, mutect2, varscan2
- ARR3 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100330833; called by muse, mutect2, varscan2
- ASB6 | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV52964789; called by muse, mutect2, varscan2
- ASPM | c.1287G>A p.W429* | Nonsense Mutation (SNP) | VAF 27/187 reads (14%) | catalogued as COSV54128199; called by muse, mutect2, varscan2
- ASTN1 | c.1706T>A p.M569K | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV56066449; called by muse, mutect2, varscan2
- ASTN2 | c.2116G>T p.G706C (on ENST00000313400 / NM_001365069.1; = p.G655C on NM_014010.5) | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57769166; called by muse, mutect2, varscan2
- ATP2B3 | c.3042C>A p.F1014L | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs181539158, COSV54844419, COSV54849515; called by muse, mutect2, varscan2
- ATP6V0D2 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 107/419 reads (26%) | catalogued as rs755514597, COSV53414236; called by muse, mutect2, varscan2
- ATP7A | c.3039G>T p.M1013I | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782746249, COSV58444823; called by muse, mutect2, varscan2
- AVIL | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 173/214 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs760997094, COSV57681225; called by muse, mutect2, varscan2
- AVPR2 | c.638T>G p.V213G | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61686061; called by muse, mutect2, varscan2
- BAP1 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 121/201 reads (60%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as rs755950173, COSV56233044; called by muse, mutect2, varscan2
- BAP1 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV56229951; called by muse, mutect2, varscan2
- BEND2 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 78/121 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs746240965, COSV66215582; called by muse, mutect2, varscan2
- BRF1 | c.1025_1026insT p.L343Pfs*104 | Frame Shift Ins (INS) | VAF 59/155 reads (38%) | catalogued as COSV100527006; called by mutect2, pindel, varscan2
- BRINP2 | c.1965C>G p.D655E | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV64176886; called by muse, mutect2, varscan2
- BRWD3 | c.1978C>A p.L660M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.702); catalogued as COSV64746706; called by muse, mutect2, varscan2
- BTRC | c.397G>A p.E133K (on ENST00000370187 / NM_033637.4; = p.E97K on NM_003939.5) | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV64560981; called by muse, mutect2, varscan2
- BUB1B | c.365T>A p.L122H | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55011304; called by muse, mutect2, varscan2
- C1orf112 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV53677961; called by muse, mutect2, varscan2
- C1orf226 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV63394936; called by muse, mutect2, varscan2
- C6 | c.1600C>A p.L534I | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54708645; called by muse, mutect2
- CACNA1G | c.4688T>C p.L1563P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV61724332; called by muse, varscan2
- CALCR | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 145/450 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.036); catalogued as COSV64007318; called by muse, mutect2, varscan2
- CCDC180 | c.4507G>T p.G1503C | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as COSV63829162; called by muse, varscan2
- CCER1 | c.99C>A p.S33R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62646482; called by mutect2, varscan2
- CDH12 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.767); catalogued as COSV66398206; called by muse, mutect2, varscan2
- CDH23 | c.6446G>T p.R2149L | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.758); catalogued as rs377376107, COSV56451092, COSV56457480; called by muse, mutect2, varscan2
- CDH8 | c.2359G>T p.G787C | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54860523; called by muse, mutect2, varscan2
- CDYL | c.371G>A p.R124K (on ENST00000328908 / NM_001368125.1; = p.R70K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV59359335; called by muse, mutect2, varscan2
- CENPE | c.3401A>T p.Q1134L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV54379516; called by muse, mutect2, varscan2
- CFTR | c.3469A>T p.M1157L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV50047550; called by muse, mutect2, varscan2
- CHD6 | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 55/145 reads (38%) | catalogued as COSV100497945, COSV58556008; called by muse, mutect2, varscan2
- CHD6 | c.1905G>T p.E635D | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV100497947; called by muse, mutect2, varscan2
- CIB3 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV54165915; called by muse, mutect2, varscan2
- CILP | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs142891097; called by muse, mutect2, varscan2
- CLCA2 | c.2382G>T p.Q794H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.417); catalogued as COSV65286807; called by muse, mutect2, varscan2
- CLN6 | c.752A>G p.K251R | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV51116573; called by muse, mutect2, varscan2
- CNTN4 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV61871320; called by muse, mutect2, varscan2
- COL12A1 | c.7355G>A p.G2452E | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224729276, COSV59393506; called by muse, mutect2, varscan2
- COL22A1 | c.3754G>T p.G1252C | Missense Mutation (SNP) | VAF 206/705 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57332308, COSV57339371; called by muse, mutect2, varscan2
- COL7A1 | c.6259C>G p.P2087A | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV60393982, COSV60402615; called by muse, mutect2, varscan2
- COPS2 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV54644968; called by muse, mutect2, varscan2
- CPS1 | c.4339C>G p.H1447D | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV51807376, COSV51810956; called by muse, mutect2, varscan2
- CRPPA | c.815C>T p.A272V (on ENST00000407010 / NM_001368197.1; = p.A222V on NM_001101417.4) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs765545106, COSV67904804; called by muse, mutect2, varscan2
- CSMD3 | c.8910T>A p.F2970L (on ENST00000297405 / NM_001363185.1; = p.F2801L on NM_052900.3) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV99828878; called by muse, mutect2, varscan2
- CSMD3 | c.8909T>A p.F2970Y (on ENST00000297405 / NM_001363185.1; = p.F2801Y on NM_052900.3) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV99828881; called by muse, mutect2, varscan2
- CTTNBP2 | c.3076T>C p.S1026P | Missense Mutation (SNP) | VAF 117/324 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs758983204, COSV50395530; called by muse, mutect2, varscan2
- CYHR1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs372867926; called by muse, mutect2, varscan2
- DAB1 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs752641705, COSV59726016, COSV59728090; called by muse, mutect2, varscan2
- DCLK1 | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as rs749408147, COSV55181436; called by muse, mutect2, varscan2
- DDB1 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 63/290 reads (22%) | catalogued as COSV57102179; called by muse, mutect2, varscan2
- DDB1 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs1474964888, COSV57102188; called by muse, mutect2, varscan2
- DDB1 | c.107A>C p.N36T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.15); catalogued as COSV57102205; called by muse, mutect2, varscan2
- DEGS2 | c.814A>G p.N272D | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV99979144; called by muse, mutect2, varscan2
- DHX57 | c.850A>T p.R284* | Nonsense Mutation (SNP) | VAF 33/150 reads (22%) | catalogued as rs200212755, COSV54884169; called by muse, mutect2, varscan2
- DIO2 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV70445038, COSV70445783; called by muse, mutect2, varscan2
- DIS3L2 | c.2205G>T p.Q735H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV56052317; called by muse, mutect2, varscan2
- DNAAF3 | c.1150T>C p.Y384H (on ENST00000524407 / NM_001256715.2; = p.Y431H on NM_178837.4) | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV61276424; called by muse, mutect2, varscan2
- DPP6 | c.431A>T p.H144L (on ENST00000377770 / NM_001364500.2; = p.H82L on NM_001936.5) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59607193; called by muse, mutect2, varscan2
- DSG3 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.524); catalogued as COSV57125491, COSV57129988; called by muse, mutect2, varscan2
- DSG4 | c.2992G>C p.G998R | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV57390450; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV50051326; called by muse, mutect2, varscan2
- DYNC1LI1 | c.467G>T p.W156L | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99818036; called by muse, mutect2, varscan2
- EBF3 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1440026193, COSV62473876; called by muse, mutect2, varscan2
- ECT2L | c.899A>G p.Y300C | Missense Mutation (SNP) | VAF 265/463 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62883940; called by muse, mutect2, varscan2
- EFNB1 | c.466C>A p.R156S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as CM157646, COSV52661425; called by muse, mutect2, varscan2
- EGFLAM | c.1769G>T p.C590F | Missense Mutation (SNP) | VAF 100/415 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59298507, COSV59298971; called by muse, mutect2, varscan2
- EIF3A | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); catalogued as COSV64961047; called by muse, mutect2, varscan2
- EIF4G3 | c.2454G>T p.T818= | Splice Region (SNP) | VAF 48/148 reads (32%) | catalogued as COSV51679669, COSV51695427; called by muse, mutect2, varscan2
- ENGASE | c.2192A>T p.E731V | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV56135107; called by muse, mutect2, varscan2
- ENOX1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs1030563488, COSV54895428; called by muse, mutect2, varscan2
- ENPP3 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV62953889; called by muse, varscan2
- EPHB6 | c.851G>T p.R284M | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV67418120; called by mutect2, varscan2
- EPS8L2 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 32/54 reads (59%) | catalogued as COSV59347513; called by muse, mutect2, varscan2
- ETS1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.713); catalogued as COSV60092923; called by muse, mutect2, varscan2
- EXOC6 | c.86+2T>C p.X29_splice | Splice Site (SNP) | VAF 47/113 reads (42%) | catalogued as COSV65316637; called by muse, mutect2
- F8 | c.3433C>A p.P1145T | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV64271964; called by muse, mutect2, varscan2
- FLG | c.1439C>G p.S480C | Missense Mutation (SNP) | VAF 119/413 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64240204; called by mutect2, varscan2
- FLNC | c.6065A>C p.K2022T | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV57954132; called by muse, mutect2, varscan2
- FTMT | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs865797696, COSV58419985; called by muse, mutect2
- FUT9 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100133274, COSV100133413; called by muse, mutect2, varscan2
- G2E3 | c.1081_1082insT p.T361Ifs*2 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as COSV52839844, COSV99249443; called by mutect2, pindel, varscan2
- GALNT14 | c.419C>A p.T140K | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.099); catalogued as COSV61104229; called by muse, mutect2, varscan2
- GLA | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV54508821; called by muse, mutect2, varscan2
- GLI3 | c.4105G>T p.G1369C | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV67887366; called by muse, mutect2, varscan2
- GPC4 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 129/699 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63697617; called by muse, mutect2, varscan2
- GPC5 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65591221; called by muse, mutect2, varscan2
- GRIK2 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 75/120 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV59728406; called by muse, mutect2, varscan2
- GRIK5 | c.1813C>A p.Q605K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53482592; called by muse, mutect2, varscan2
- HCFC1 | c.5588A>C p.K1863T | Missense Mutation (SNP) | VAF 104/730 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60071346; called by muse, mutect2, varscan2
- HCFC1 | c.5036C>A p.A1679D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.039); catalogued as rs868931749, COSV60071356; called by muse, mutect2, varscan2
- HDX | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV52975366; called by muse, mutect2, varscan2
- HMGB3 | c.235G>T p.G79* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | catalogued as COSV57485838; called by muse, mutect2, varscan2
- HMGB4 | c.353G>T p.W118L | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV53880525, COSV53885718; called by muse, mutect2, varscan2
- HRH2 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99199560; called by muse, mutect2, varscan2
- IGSF11 | c.337T>A p.S113T (on ENST00000393775 / NM_001015887.3; = p.S112T on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/88 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as COSV61168327; called by muse, mutect2, varscan2
- IL1R1 | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs1165978881, COSV52105678; called by muse, mutect2, varscan2
- ITGAX | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV51644583; called by muse, mutect2, varscan2
- KCNH6 | c.1375G>T p.V459L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV59002547; called by muse, mutect2, varscan2
- KCNJ16 | c.602G>T p.W201L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99388073; called by muse, mutect2, varscan2
- KCNMA1 | c.2381C>A p.P794H (on ENST00000286628 / NM_001161352.2; = p.P736H on NM_002247.4) | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV54241337; called by muse, mutect2, varscan2
- KDM4D | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV58634293; called by muse, mutect2, varscan2
- KEAP1 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV50268536, COSV50673043; called by muse, mutect2, varscan2
- KIAA1210 | c.3302C>A p.S1101Y | Missense Mutation (SNP) | VAF 96/466 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV68176620; called by muse, mutect2, varscan2
- KIAA1614 | c.2929G>A p.G977R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as rs1263685754, COSV62550715; called by muse, mutect2
- KLC1 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 12/128 reads (9%) | catalogued as COSV99871316; called by muse, mutect2
- KLHL14 | c.1115A>C p.N372T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63830869, COSV63831972; called by muse, mutect2, varscan2
- KNTC1 | c.5347A>C p.N1783H | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.364); catalogued as COSV61079674; called by muse, mutect2, varscan2
- KPNA1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 86/134 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs376884067; called by muse, mutect2, varscan2
- KRT1 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 118/148 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52866127; called by muse, mutect2, varscan2
- KRT13 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs748841601, COSV55839660; called by muse, mutect2, varscan2
- LCOR | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV53715349; called by muse, mutect2, varscan2
- LIN9 | c.342A>T p.K114N (on ENST00000366808 / NM_001270410.2; = p.K59N on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); catalogued as COSV100068061, COSV60244654; called by muse, mutect2, varscan2
- LMBRD2 | c.1916G>T p.R639M | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV56949433; called by muse, mutect2, varscan2
- LRR1 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100023052; called by muse, mutect2, varscan2
- LRRK2 | c.5953C>T p.L1985F | Missense Mutation (SNP) | VAF 125/236 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110935, COSV54149833; called by muse, mutect2, varscan2
- LTBP2 | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745464603, COSV56206950, COSV56210168; called by muse, mutect2, varscan2
- MAGEA4 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.242); catalogued as COSV99367387; called by muse, mutect2, varscan2
- MAGEA6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100262733; called by muse, mutect2, varscan2
- MAP3K9 | c.2866G>T p.G956C (on ENST00000554752 / NM_001284230.1; = p.G970C on NM_033141.4) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as COSV67120861; called by muse, mutect2, varscan2
- MC5R | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.791); catalogued as COSV61254411; called by muse, mutect2, varscan2
- MCF2 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 26/159 reads (16%) | catalogued as COSV58482433, COSV58483565; called by muse, mutect2, varscan2
- MELK | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV53198186; called by muse, mutect2, varscan2
- MEPE | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV63072464; called by muse, mutect2, varscan2
- MIS18BP1 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV60370177; called by muse, mutect2, varscan2
- MLF2 | c.229A>G p.M77V | Missense Mutation (SNP) | VAF 76/92 reads (83%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs61731916; called by muse, mutect2, varscan2
- MME | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV64706839; called by muse, varscan2
- MORF4L1 | c.167G>T p.R56M | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV58704219; called by muse, mutect2, varscan2
- MRC2 | c.3662C>T p.T1221I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV57638728; called by muse, mutect2, varscan2
- MRM2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV99642599; called by muse, varscan2
- MRPL13 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1159805809, COSV59962162; called by muse, mutect2, varscan2
- MSLN | c.341A>T p.D114V | Missense Mutation (SNP) | VAF 126/223 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53500936; called by muse, mutect2, varscan2
- MT1G | c.49G>T p.A17S (on ENST00000379811 / NM_001301267.2; = p.A16S on NM_005950.3) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.111); catalogued as COSV60090804; called by muse, mutect2, varscan2
- MUC16 | c.11198T>A p.L3733Q | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV67459157; called by muse, mutect2, varscan2
- MXRA5 | c.848del p.P283Lfs*2 | Frame Shift Del (DEL) | VAF 55/183 reads (30%) | catalogued as COSV54244704; called by mutect2, pindel, varscan2
- MYH2 | c.1907G>A p.G636D | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV55435622; called by muse, mutect2
- MYH6 | c.2608G>T p.A870S | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs1475742505, COSV62449442; called by muse, mutect2, varscan2
- MYO16 | c.933G>T p.W311C | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51787614; called by muse, mutect2, varscan2
- MYO5B | c.579A>C p.E193D | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV53216116; called by muse, mutect2, varscan2
- NELL1 | c.1936G>C p.V646L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV54255090; called by muse, mutect2, varscan2
- NFKB2 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); catalogued as COSV50044466; called by muse, mutect2, varscan2
- NHLRC2 | c.742A>G p.I248V | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.045); catalogued as COSV65174696; called by muse, mutect2, varscan2
- NOP14 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV58624820; called by mutect2, varscan2
- NPHS1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62287323, COSV62287505; called by muse, mutect2, varscan2
- NPTX2 | c.1141C>G p.R381G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55716820, COSV55717396, COSV99675047; called by muse, mutect2, varscan2
- NRDE2 | c.356A>T p.D119V | Missense Mutation (SNP) | VAF 81/327 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV62962810; called by muse, mutect2, varscan2
- NSD2 | c.2593G>T p.G865C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56389304; called by muse, mutect2, varscan2
- NTRK2 | c.2213G>C p.S738T (on ENST00000323115 / NM_001369534.1; = p.S754T on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52860948; called by muse, mutect2, varscan2
- NTRK3 | c.1382A>G p.K461R | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV58117854; called by muse, mutect2, varscan2
- NUTM1 | c.2368G>A p.G790S | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV59216523; called by muse, mutect2, varscan2
- OCRL | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as rs776946722, COSV63980679; called by muse, mutect2, varscan2
- OR1S1 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.819); catalogued as COSV58706751; called by muse, mutect2, varscan2
- OR2M3 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV71758982; called by muse, mutect2, varscan2
- OR3A2 | c.896A>G p.Y299C | Missense Mutation (SNP) | VAF 61/94 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101375046; called by muse, mutect2, varscan2
- OR4A5 | c.154T>C p.S52P | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV60522194; called by muse, mutect2, varscan2
- OR4C46 | c.660G>C p.L220F | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV60218373, COSV60218892; called by muse, mutect2, varscan2
- OR5L1 | c.157T>A p.S53T | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV61733026, COSV61733519; called by muse, mutect2, varscan2
- PAPSS1 | c.1295T>C p.M432T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54488544; called by muse, varscan2
- PAX4 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV58387486; called by muse, mutect2, varscan2
- PCDH11X | c.2431G>T p.V811F | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53457151; called by muse, mutect2, varscan2
- PCDH11X | c.2890C>A p.Q964K | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100009947; called by muse, mutect2, varscan2
- PCDHB12 | c.652G>C p.G218R | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782228863, COSV53395326, COSV53400108, COSV53402187; called by muse, mutect2, varscan2
- PDCD6IP | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56242622; called by muse, mutect2, varscan2
- PHF20 | c.1400A>T p.K467I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV59185552; called by muse, mutect2, varscan2
- PIM2 | c.647C>G p.A216G | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV99900063; called by muse, mutect2, varscan2
- POF1B | c.1105C>A p.Q369K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53132864; called by muse, mutect2, varscan2
- PRDX4 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV65025915; called by muse, mutect2, varscan2
- PREPL | c.1141G>T p.V381F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV53216177; called by muse, mutect2, varscan2
- PZP | c.2294C>A p.P765H | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54358153; called by muse, mutect2, varscan2
- RB1CC1 | c.2618A>T p.E873V | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as COSV50245968; called by muse, mutect2, varscan2
- RET | c.1379A>T p.D460V | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV60691243; called by muse, mutect2, varscan2
- RFC2 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.014); catalogued as COSV50016072; called by muse, mutect2, varscan2
- RND3 | c.614T>G p.V205G | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as COSV55724074; called by muse, mutect2, varscan2
- RNF13 | c.1076A>G p.N359S | Missense Mutation (SNP) | VAF 80/109 reads (73%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99525923; called by muse, mutect2, varscan2
- RNF150 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1271016427, COSV60789453; called by muse, mutect2, varscan2
- RUFY2 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61190918, COSV99062687; called by muse, mutect2, varscan2
- RXRG | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV63231874; called by muse, mutect2, varscan2
- RYR2 | c.2211T>G p.I737M | Missense Mutation (SNP) | VAF 118/398 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV63678495; called by muse, mutect2, varscan2
- SAMD9L | c.1894A>G p.R632G | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as COSV59080781; called by muse, mutect2, varscan2
- SATB2 | c.473+1G>T p.X158_splice | Splice Site (SNP) | VAF 42/153 reads (27%) | catalogued as COSV53481962; called by muse, mutect2, varscan2
- SCAF1 | c.166+1G>A p.X56_splice | Splice Site (SNP) | VAF 56/110 reads (51%) | catalogued as COSV62182965; called by muse, mutect2, varscan2
- SCFD2 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs1297662053, COSV66370713; called by muse, mutect2, varscan2
- SEMA6D | c.2736G>T p.M912I (on ENST00000316364 / NM_153618.2; = p.M850I on NM_020858.2) | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100316662; called by muse, mutect2, varscan2
- SEMA6D | c.2737G>T p.G913* (on ENST00000316364 / NM_153618.2; = p.G851* on NM_020858.2) | Nonsense Mutation (SNP) | VAF 62/224 reads (28%) | catalogued as COSV100316909, COSV60381937; called by muse, mutect2, varscan2
- SERPINA11 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 90/394 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); catalogued as rs186102883, COSV58241594; called by muse, mutect2, varscan2
- SFMBT2 | c.2144C>A p.S715* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV62808087; called by muse, mutect2, varscan2
- SHE | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV100495908; called by muse, mutect2, varscan2
- SHOX2 | c.594A>C p.Q198H (on ENST00000441443 / NM_006884.3; = p.Q222H on NM_003030.4) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.298); catalogued as COSV101273749, COSV67463767; called by muse, mutect2
- SHROOM3 | c.4279C>T p.P1427S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV56027222; called by muse, mutect2
- SIGLEC10 | c.1065C>A p.N355K | Missense Mutation (SNP) | VAF 156/256 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV59480838; called by mutect2, varscan2
- SKIL | c.1507A>G p.K503E | Missense Mutation (SNP) | VAF 100/146 reads (68%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs996741608, COSV52059377; called by muse, mutect2, varscan2
- SLC26A11 | c.1043C>A p.T348N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV63279252; called by muse, mutect2, varscan2
- SLC30A10 | c.1414A>T p.K472* | Nonsense Mutation (SNP) | VAF 150/483 reads (31%) | catalogued as COSV63071034, COSV99055453; called by muse, mutect2, varscan2
- SLC35E3 | c.799G>T p.G267* | Nonsense Mutation (SNP) | VAF 73/125 reads (58%) | catalogued as COSV60117803; called by muse, mutect2, varscan2
- SLC37A2 | c.77T>A p.L26Q | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53521648; called by muse, mutect2, varscan2
- SLC38A11 | c.290G>A p.R97H (on ENST00000409149 / NM_001351539.1; = p.R75H on NM_173512.2) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs914142729, COSV58053143; called by muse, mutect2, varscan2
- SNX31 | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 160/289 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61262706, COSV61264249; called by muse, mutect2, varscan2
- SORCS3 | c.1516A>T p.K506* | Nonsense Mutation (SNP) | VAF 41/127 reads (32%) | catalogued as COSV63807479; called by muse, mutect2, varscan2
- SOWAHD | c.843G>T p.R281S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59649551, COSV59649929; called by muse, mutect2, varscan2
- SPATA20 | c.1429G>T p.V477L (on ENST00000356488 / NM_001258372.1; = p.V493L on NM_022827.4) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV99135645; called by muse, mutect2, varscan2
- ST8SIA5 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 37/86 reads (43%) | PolyPhen probably damaging (0.999); catalogued as COSV59331141, COSV59331955; called by muse, mutect2, varscan2
- STAG3 | c.2921A>G p.Q974R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57929152; called by muse, mutect2, varscan2
- STARD8 | c.1325C>G p.S442C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV52924705; called by muse, varscan2
- STARD8 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV52924732; called by muse, varscan2
- STK32A | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100097063, COSV60417388; called by muse, mutect2, varscan2
- SUMF2 | c.329G>A p.G110E (on ENST00000652303; = p.G91E on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766756211, COSV51915960; called by muse, mutect2, varscan2
- SUN1 | c.1946G>T p.G649V (on ENST00000405266 / NM_001367651.1; = p.G529V on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101273077, COSV67448536, COSV67451638; called by muse, mutect2, varscan2
- SVIL | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs531587959, COSV63442319; called by muse, mutect2, varscan2
- SYNE3 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as COSV62078987; called by muse, mutect2, varscan2
- SYTL4 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52167003; called by muse, mutect2, varscan2
- TAAR1 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99257507; called by muse, mutect2, varscan2
- TAS1R2 | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV64744459; called by muse, mutect2, varscan2
- TCF23 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV99940301; called by muse, mutect2, varscan2
- TENM1 | c.3545G>T p.C1182F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV64429786; called by muse, mutect2, varscan2
- TENM1 | c.1092del p.N365Tfs*33 | Frame Shift Del (DEL) | VAF 52/358 reads (15%) | catalogued as COSV100950282; called by pindel, varscan2
- TEX13A | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV61151729; called by muse, mutect2, varscan2
- THEMIS | c.1098C>G p.H366Q | Missense Mutation (SNP) | VAF 107/158 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64070519; called by muse, mutect2, varscan2
- THOC2 | c.2383A>T p.K795* | Nonsense Mutation (SNP) | VAF 89/490 reads (18%) | catalogued as COSV55544248; called by muse, mutect2, varscan2
- THSD7A | c.3910C>A p.L1304I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.771); catalogued as COSV69855625; called by muse, mutect2, varscan2
- TMEM176A | c.36G>T p.E12D | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.112); catalogued as COSV50240744; called by muse, mutect2, varscan2
- TMTC1 | c.460C>T p.H154Y (on ENST00000539277 / NM_001193451.2; = p.H46Y on NM_175861.3) | Missense Mutation (SNP) | VAF 109/146 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55479286; called by muse, mutect2, varscan2
- TOP2A | c.3627A>C p.E1209D | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV70732400; called by muse, mutect2, varscan2
- TPTE | c.417G>T p.M139I (on ENST00000618007 / NM_199261.4; = p.M121I on NM_199259.4) | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs756602065; called by muse, varscan2
- TRIM65 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs150794170; called by muse, mutect2, varscan2
- TRPC4 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58997000; called by muse, mutect2, varscan2
- TRPC5 | c.1586T>C p.L529P | Missense Mutation (SNP) | VAF 121/323 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53288147; called by muse, mutect2, varscan2
- TTN | c.44738C>A p.P14913H (on ENST00000591111; = p.P7489H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | PolyPhen probably damaging (0.947); catalogued as COSV59988582, COSV59998730; called by muse, mutect2, varscan2
- TULP4 | c.1700G>T p.R567L | Missense Mutation (SNP) | VAF 59/92 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65572777, COSV65574343; called by muse, mutect2, varscan2
- UHRF2 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371648083; called by muse, mutect2, varscan2
- UTP6 | c.1598A>T p.Y533F | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as COSV55572624; called by muse, mutect2, varscan2
- VGLL1 | c.115A>T p.S39C | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65703183; called by muse, mutect2, varscan2
- VWCE | c.1531G>T p.G511W | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57111776, COSV57111784; called by muse, mutect2, varscan2
- WDPCP | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV55417229; called by muse, mutect2, varscan2
- WNK3 | c.2251-2A>T p.X751_splice | Splice Site (SNP) | VAF 65/262 reads (25%) | catalogued as COSV63613155; called by muse, mutect2, varscan2
- YIPF1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs763286681, COSV50777057, COSV50780000; called by muse, mutect2, varscan2
- YIPF6 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65855575; called by muse, mutect2, varscan2
- YTHDF3 | c.352T>C p.F118L | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV72773428; called by muse, mutect2, varscan2
- ZBTB33 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100434106; called by muse, mutect2, varscan2
- ZCCHC7 | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 115/182 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV59719048; called by muse, mutect2, varscan2
- ZFHX4 | c.2832G>T p.Q944H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV50677538; called by muse, mutect2, varscan2
- ZNF264 | c.1189A>T p.K397* | Nonsense Mutation (SNP) | VAF 36/69 reads (52%) | catalogued as COSV54041455; called by muse, mutect2, varscan2
- ZNF300 | c.625A>G p.R209G | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.306); catalogued as COSV51033911; called by muse, mutect2
- ZNF398 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV60065054; called by muse, mutect2, varscan2
- ZNF492 | c.183T>A p.N61K | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs750501823, COSV71761739; called by muse, mutect2, varscan2
- ZNF582 | c.862T>A p.C288S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56731825; called by muse, mutect2, varscan2
- ZNF804B | c.3919A>G p.I1307V | Missense Mutation (SNP) | VAF 151/457 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1166342690, COSV60823705; called by muse, mutect2, varscan2
- ZNF831 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100926188, COSV64039134; called by muse, mutect2, varscan2
- ZNF862 | c.2880A>T p.E960D | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV56223545; called by muse, mutect2, varscan2
- BEGAIN | c.268del p.R90Vfs*3 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- EMILIN3 | c.908A>T p.Y303F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FLG | c.7174del p.H2392Ifs*27 | Frame Shift Del (DEL) | VAF 90/405 reads (22%) | called by mutect2, pindel, varscan2
- FOXP1 | c.819del p.H274Mfs*51 | Frame Shift Del (DEL) | VAF 70/136 reads (51%) | called by mutect2, pindel, varscan2
- GALNT8 | c.93del p.T32Lfs*18 | Frame Shift Del (DEL) | VAF 154/202 reads (76%) | called by mutect2, varscan2
- GRM8 | c.2463del p.M822* | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | called by mutect2, pindel, varscan2
- HEPH | c.2564-2del p.X855_splice (on ENST00000343002; = p.X588_splice on NM_014799.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- HYDIN | c.13216del p.I4406Sfs*8 | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | called by mutect2, pindel, varscan2
- IGKV1D-13 | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- IGKV1D-16 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IGKV2-30 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- JPH2 | c.1801dup p.T601Nfs*41 | Frame Shift Ins (INS) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- LNX2 | c.553_554dup p.V186Qfs*8 | Frame Shift Ins (INS) | VAF 147/411 reads (36%) | called by mutect2, pindel, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, pindel, varscan2
- PLXNA3 | c.1745dup p.N582Kfs*10 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- PRDM4 | c.331+1del p.X111_splice | Splice Site (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- PSKH1 | c.1135dup p.A379Gfs*24 | Frame Shift Ins (INS) | VAF 44/109 reads (40%) | called by mutect2, pindel, varscan2
- SLC35F4 | c.217_219dup p.S73dup (on ENST00000339762 / NM_001352015.2; = p.S37dup on NM_001206920.1 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- TPSB2 | c.722T>A p.V241E | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- TPTE | c.418G>T p.D140Y (on ENST00000618007 / NM_199261.4; = p.D122Y on NM_199259.4) | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TRAV26-1 | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TTN | c.22504del p.E7502Rfs*11 (on ENST00000591111; = p.E6575Rfs*11 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- UNC13D | c.580_582del p.D194del | In Frame Del (DEL) | VAF 92/452 reads (20%) | called by mutect2, pindel*, varscan2*
- WDR49 | c.474_482dup p.L160_K161insNIL (on ENST00000308378 / NM_001366158.1; = p.L501_K502insNIL on NM_001348951.2 and 2 other RefSeq transcripts) | In Frame Ins (INS) | VAF 78/164 reads (48%) | called by mutect2, varscan2
- ZNF648 | c.1326C>G p.H442Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AQP3 | c.216C>A p.L72= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV99955525; called by muse, mutect2, varscan2
- ASTL | c.432C>T p.F144= | Silent (SNP) | VAF 38/183 reads (21%) | catalogued as COSV60904003; called by muse, mutect2, varscan2
- BCKDHB | c.957G>C p.V319= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV100243361; called by muse, mutect2
- C3orf56 | c.243G>C p.V81= | Silent (SNP) | VAF 86/112 reads (77%) | catalogued as rs184339868, COSV101228933; called by muse, mutect2, varscan2
- CDH8 | c.876C>A p.G292= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV54860537; called by muse, mutect2, varscan2
- COL4A1 | c.3216G>C p.A1072= | Silent (SNP) | VAF 104/305 reads (34%) | catalogued as COSV65424092; called by muse, mutect2, varscan2
- CRACD | c.2253G>A p.L751= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs763679684, COSV51719204; called by muse, mutect2, varscan2
- CTNND2 | c.1233G>C p.R411= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV58879986; called by muse, mutect2, varscan2
- CUBN | c.7773G>A p.R2591= | Silent (SNP) | VAF 56/175 reads (32%) | catalogued as COSV64713293; called by muse, mutect2, varscan2
- CXorf38 | c.381A>G p.K127= | Silent (SNP) | VAF 59/108 reads (55%) | catalogued as COSV59947451; called by muse, mutect2, varscan2
- DSTYK | c.528G>T p.T176= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV65686131; called by muse, mutect2, varscan2
- FAM110B | c.291G>T p.T97= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV100826111, COSV64064534; called by muse, mutect2, varscan2
- FAT3 | c.1179C>T p.V393= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs761990294, COSV53098275; called by mutect2, varscan2
- FRG2 | c.534T>A p.S178= | Silent (SNP) | VAF 59/139 reads (42%) | called by muse, mutect2, varscan2
- GABRQ | c.1635C>T p.A545= | Silent (SNP) | VAF 55/164 reads (34%) | catalogued as COSV64781583; called by muse, mutect2, varscan2
- GALNT7 | c.576A>G p.L192= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV53928713; called by muse, mutect2, varscan2
- GPR141 | c.624G>T p.V208= | Silent (SNP) | VAF 107/321 reads (33%) | catalogued as COSV57731951; called by muse, mutect2, varscan2
- HK1 | c.1392C>T p.A464= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs192297958, COSV53856435; called by muse, mutect2, varscan2
- HLA-DOA | c.219G>A p.E73= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV57713977; called by muse, mutect2, varscan2
- HR | c.1146A>T p.T382= | Silent (SNP) | VAF 148/268 reads (55%) | catalogued as COSV57191577; called by muse, mutect2, varscan2
- ICE1 | c.4302A>T p.P1434= | Silent (SNP) | VAF 47/152 reads (31%) | catalogued as COSV56822523; called by muse, mutect2, varscan2
- IFNA10 | c.186C>T p.P62= | Silent (SNP) | VAF 73/131 reads (56%) | catalogued as COSV99497404; called by muse, mutect2, varscan2
- IGSF1 | c.996G>C p.V332= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as COSV63836939; called by muse, mutect2, varscan2
- IRAK1 | c.1602C>A p.A534= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV64110559; called by muse, mutect2, varscan2
- KCNA5 | c.1701G>T p.G567= | Silent (SNP) | VAF 63/90 reads (70%) | catalogued as COSV52904983; called by muse, mutect2, varscan2
- MARCHF1 | c.255C>T p.C85= (on ENST00000274056; = p.C68= on NM_017923.4) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs776363990, COSV56812512, COSV56819636; called by muse, mutect2, varscan2
- MED16 | c.996A>G p.K332= | Silent (SNP) | VAF 79/133 reads (59%) | catalogued as COSV54125317; called by muse, mutect2, varscan2
- MGA | c.8481C>T p.L2827= (on ENST00000219905 / NM_001164273.1; = p.L2618= on NM_001080541.2) | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as COSV54951959; called by muse, mutect2, varscan2
- MLXIPL | c.897C>T p.I299= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV57667763; called by muse, mutect2, varscan2
- MMP19 | c.1287C>A p.P429= | Silent (SNP) | VAF 267/334 reads (80%) | catalogued as COSV59451089; called by muse, mutect2, varscan2
- MN1 | c.177G>T p.P59= | Silent (SNP) | VAF 59/100 reads (59%) | catalogued as COSV56557613; called by muse, varscan2
- MSH4 | c.1926T>C p.D642= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs778369232, COSV54200943; called by muse, mutect2, varscan2
- MTCL1 | c.2067G>T p.G689= (on ENST00000306329 / NM_001378206.1; = p.G329= on NM_015210.4) | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV60405206; called by muse, mutect2, varscan2
- MYF6 | c.232C>T p.L78= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV57351294; called by muse, mutect2, varscan2
- NEIL3 | c.525G>C p.R175= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV52809708; called by muse, mutect2, varscan2
- OR2AK2 | c.915G>A p.L305= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV63551623; called by muse, mutect2, varscan2
- OR5K1 | c.99C>A p.A33= | Silent (SNP) | VAF 167/265 reads (63%) | catalogued as COSV60303946; called by muse, mutect2, varscan2
- OTOF | c.1464C>T p.F488= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as COSV55500775, COSV55502729; called by muse, mutect2, varscan2
- PALD1 | c.1482G>T p.A494= | Silent (SNP) | VAF 74/193 reads (38%) | catalogued as COSV54972369; called by muse, mutect2, varscan2
- PCDH11X | c.2889C>A p.I963= | Silent (SNP) | VAF 97/342 reads (28%) | catalogued as COSV100009936; called by muse, mutect2, varscan2
- PITPNM3 | c.435G>A p.G145= | Silent (SNP) | VAF 45/73 reads (62%) | catalogued as COSV52594821; called by muse, mutect2, varscan2
- PKHD1 | c.8973G>A p.V2991= | Silent (SNP) | VAF 29/263 reads (11%) | catalogued as COSV61870075; called by muse, mutect2, varscan2
- PLA2G2E | c.54C>A p.T18= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV64290428; called by muse, mutect2, varscan2
- PLEKHO1 | c.921G>A p.R307= | Silent (SNP) | VAF 55/160 reads (34%) | catalogued as COSV50310102, COSV50310604; called by muse, mutect2, varscan2
- PLPPR4 | c.1659T>C p.A553= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as COSV64565334; called by muse, mutect2, varscan2
- PLXNA2 | c.843G>T p.V281= | Silent (SNP) | VAF 79/205 reads (39%) | catalogued as COSV65439761; called by muse, mutect2, varscan2
- PLXNB3 | c.3366C>A p.V1122= | Silent (SNP) | VAF 45/215 reads (21%) | catalogued as COSV100738007, COSV62796775; called by muse, mutect2, varscan2
- PNPLA1 | c.489G>A p.P163= (on ENST00000394571 / NM_001374623.1; = p.P68= on NM_173676.2) | Silent (SNP) | VAF 89/219 reads (41%) | catalogued as rs572266889, COSV100462820; called by muse, mutect2, varscan2
- POLR3A | c.402G>T p.L134= | Silent (SNP) | VAF 72/208 reads (35%) | catalogued as COSV64930828; called by muse, mutect2, varscan2
- PPARA | c.282C>T p.P94= | Silent (SNP) | VAF 53/68 reads (78%) | catalogued as COSV53078029; called by muse, mutect2, varscan2
- PPFIA4 | c.273G>C p.R91= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV55313854; called by muse, mutect2, varscan2
- PRAMEF5 | c.324C>G p.V108= | Silent (SNP) | VAF 70/356 reads (20%) | catalogued as COSV100871208; called by muse, varscan2
- PYHIN1 | c.1092C>T p.I364= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs578100050, COSV63722065; called by muse, mutect2, varscan2
- RAMP1 | c.249C>T p.F83= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV54537861; called by muse, mutect2, varscan2
- RBL2 | c.2109A>G p.L703= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV50875350; called by muse, mutect2, varscan2
- RHOJ | c.357C>A p.L119= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV57457747; called by muse, mutect2, varscan2
- RXFP1 | c.2049G>T p.L683= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV57048774; called by muse, mutect2, varscan2
- RYR2 | c.1014G>A p.L338= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV63678486; called by muse, mutect2, varscan2
- SCN8A | c.5133G>T p.L1711= | Silent (SNP) | VAF 123/145 reads (85%) | catalogued as COSV61979639; called by muse, mutect2, varscan2
- SDK1 | c.3894A>G p.T1298= | Silent (SNP) | VAF 69/261 reads (26%) | catalogued as COSV67364223; called by muse, mutect2, varscan2
- SLC28A2 | c.792C>T p.I264= | Silent (SNP) | VAF 17/189 reads (9%) | catalogued as rs114596394; called by muse, mutect2
- SLC30A6 | c.330G>A p.L110= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV50872312; called by muse, mutect2, varscan2
- SLC4A1 | c.777G>T p.P259= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV52259398, COSV99293102; called by muse, mutect2, varscan2
- SNTG1 | c.339G>T p.V113= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV52437126; called by muse, mutect2, varscan2
- SRPX2 | c.670C>A p.R224= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as COSV65933187, COSV65934412; called by muse, mutect2, varscan2
- TAAR5 | c.45A>T p.A15= | Silent (SNP) | VAF 85/125 reads (68%) | catalogued as COSV57798837; called by muse, mutect2, varscan2
- TBC1D25 | c.189C>A p.L63= | Silent (SNP) | VAF 62/267 reads (23%) | catalogued as COSV100952119, COSV65123530; called by muse, mutect2, varscan2
- TCIRG1 | c.2370G>A p.V790= | Silent (SNP) | VAF 31/211 reads (15%) | catalogued as COSV55835165; called by muse, mutect2, varscan2
- TENM1 | c.6210C>A p.V2070= | Silent (SNP) | VAF 50/287 reads (17%) | catalogued as COSV64429772; called by muse, mutect2, varscan2
- TENM3 | c.5200A>C p.R1734= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV101304963; called by muse, mutect2, varscan2
- TMPRSS11F | c.987C>A p.V329= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as COSV62465932; called by muse, mutect2, varscan2
- TRIB2 | c.990G>A p.P330= | Silent (SNP) | VAF 49/106 reads (46%) | catalogued as rs771800128, COSV50224810, COSV50232086; called by muse, mutect2, varscan2
- UNC79 | c.3525G>A p.L1175= (on ENST00000393151 / NM_001346218.2; = p.L998= on NM_020818.5) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV56382683; called by muse, mutect2, varscan2
- VWA2 | c.765C>T p.G255= | Silent (SNP) | VAF 67/169 reads (40%) | catalogued as rs1260463225, COSV53905990; called by muse, mutect2, varscan2
- WSCD1 | c.597G>T p.R199= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as rs749668891, COSV58494931; called by muse, mutect2, varscan2
- XIRP2 | c.633C>A p.T211= (on ENST00000628543; = p.T386= on NM_152381.6) | Silent (SNP) | VAF 66/177 reads (37%) | catalogued as COSV54693591; called by muse, mutect2, varscan2
- ZKSCAN8 | c.309A>G p.L103= | Silent (SNP) | VAF 70/130 reads (54%) | catalogued as COSV57637548; called by muse, mutect2, varscan2
- ZNF804A | c.2316T>C p.R772= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs188620484, COSV56444180, COSV56474185; called by muse, mutect2, varscan2
- AFF3 | c.54-2603A>G | Intron (SNP) | VAF 38/202 reads (19%) | catalogued as COSV100418302; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840319 C>T | 5'Flank (SNP) | VAF 36/131 reads (27%) | catalogued as COSV100005821; called by muse, mutect2, varscan2
- CAMKK1 | c.685+165G>A | Intron (SNP) | VAF 9/107 reads (8%) | catalogued as COSV99340083; called by muse, mutect2
- FOLH1B | n.896T>C | RNA (SNP) | VAF 17/68 reads (25%) | catalogued as rs1565412915; called by muse, mutect2, varscan2
- IGKV1-13 | n.288C>A | RNA (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- MINK1 | c.2401-138G>A | Intron (SNP) | VAF 12/61 reads (20%) | catalogued as rs770343995, COSV99544701; called by muse, mutect2, varscan2
- NTRK3 | c.1586-40541C>A | Intron (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100446113, COSV58113350; called by muse, varscan2
- PCSK6 | c.1414+20G>T | Intron (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- PDE4B | c.635-102del | Intron (DEL) | VAF 13/71 reads (18%) | catalogued as COSV58485675; called by mutect2, pindel, varscan2
- PRRX1 | c.599+3881C>A | Intron (SNP) | VAF 136/418 reads (33%) | catalogued as COSV53420271, COSV99509435; called by muse, mutect2, varscan2
- SNORD115-19 | n.65A>G | RNA (SNP) | VAF 141/343 reads (41%) | called by muse, mutect2, varscan2
- SSPOP | n.6064G>T | RNA (SNP) | VAF 14/28 reads (50%) | catalogued as COSV50487129; called by muse, varscan2
